Somatic mutation profile of tumor specimen C3L-01744-01 (aliquot CPT0093280009) from CPTAC case C3L-01744, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,808 days).
Specimen C3L-01744-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 370302ea-e4f8-4fa1-857a-2ddd5916c3a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01744-31 (Blood Derived Normal), aliquot CPT0093320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c96bef5-29ec-40eb-9a73-05cbdc0281b8

The open-access MAF lists 1,927 somatic variants for this specimen: 1,261 protein-altering or splice-affecting, 380 silent, 286 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 930, Silent 380, Intron 151, Frame Shift Del 128, Frame Shift Ins 103, Nonsense Mutation 63, 3'UTR 50, RNA 29, Splice Site 23, 5'UTR 22, 5'Flank 20, 3'Flank 14.

Variants (750 of 1,927; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6A | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868064163, COSV52023332; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.2604+1G>A p.X868_splice | Splice Site (SNP) | VAF 76/256 reads (30%) | catalogued as rs775345377; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 52/125 reads (42%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- ATP1A2 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 184/480 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765909830, CM041246; ClinVar: likely pathogenic; called by muse, varscan2
- CHEK2 | c.1005dup p.D336* (on ENST00000382580 / NM_001005735.2; = p.D293* on NM_007194.4) | Frame Shift Ins (INS) | VAF 80/223 reads (36%) | catalogued as rs772683219; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DDX3X | c.974G>A p.R325H (on ENST00000399959; = p.R326H on NM_001356.5) | Missense Mutation (SNP) | VAF 212/586 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs797045025, CM158024, COSV101302329; ClinVar: pathogenic; called by muse, varscan2
- DYNC1H1 | c.10573C>T p.R3525C | Missense Mutation (SNP) | VAF 227/557 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 73/217 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXC1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 158/618 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307884, CM014797, CM162322; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1679G>A p.R560Q (on ENST00000359125 / NM_172107.4; = p.R532Q on NM_004518.6) | Missense Mutation (SNP) | VAF 144/323 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517919, COSV60556829; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 56/135 reads (41%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- MAK | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 128/357 reads (36%) | catalogued as rs753314164, COSV57564849; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OBSL1 | c.690dup p.E231Rfs*23 | Frame Shift Ins (INS) | VAF 107/337 reads (32%) | catalogued as rs1553538488; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- OPLAH | c.2608dup p.H870Pfs*92 | Frame Shift Ins (INS) | VAF 30/124 reads (24%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, varscan2
- PMS2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 202/523 reads (39%) | catalogued as rs63750871, CM950967, COSV99764106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 176/446 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs398123320, COSV64297602, COSV64303463, COSV64307402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 170/424 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.19dup p.R7Pfs*24 | Frame Shift Ins (INS) | VAF 127/362 reads (35%) | catalogued as rs1131690852; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RPE65 | c.1067dup p.N356Kfs*9 | Frame Shift Ins (INS) | VAF 112/345 reads (32%) | catalogued as rs281865520; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- SACS | c.5719C>T p.R1907* | Nonsense Mutation (SNP) | VAF 68/274 reads (25%) | catalogued as rs1485209013, CM131363, COSV66547198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SETBP1 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 121/478 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267607042, CM103046, COSV56311800, COSV56326819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XPC | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 86/195 reads (44%) | catalogued as rs764321665, CM1211176, COSV53208194; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV99367693; called by muse, mutect2, varscan2
- ABCC11 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 115/294 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs139927866, COSV62325795; called by muse, mutect2, varscan2
- ABR | c.2459C>T p.A820V (on ENST00000302538 / NM_021962.5; = p.A783V on NM_001092.5) | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs747439385, COSV52149664; called by muse, varscan2
- ABRA | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs148182297, COSV61733215; called by muse, mutect2, varscan2
- AC069544.2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.102); catalogued as rs1449045382, COSV101000705; called by muse, mutect2
- AC136428.1 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 103/274 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs766293744; called by muse, mutect2, varscan2
- ACAA1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776632031, COSV57179750; called by muse, mutect2, varscan2
- ACOT12 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV100297251; called by muse, varscan2
- ADARB2 | c.1537A>G p.R513G | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs770509238; called by muse, mutect2, varscan2
- ADD2 | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs868954956; called by muse, mutect2, varscan2
- ADGRE2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs751483105, COSV59692041; called by muse, mutect2, varscan2
- ADGRG6 | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 166/447 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1425955493, COSV99746024; called by muse, mutect2, varscan2
- ADPRHL1 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 153/326 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs766931087; called by muse, mutect2, varscan2
- ADRA1B | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs1273352160, COSV60701265; called by muse, mutect2, varscan2
- ADRA2A | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 73/248 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54530084; called by muse, mutect2, varscan2
- AGO2 | c.394A>G p.I132V | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs750522568; called by muse, mutect2, varscan2
- AGRN | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 181/497 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as rs1295689490; called by muse, mutect2, varscan2
- AHCYL1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs1445076232; called by muse, mutect2, varscan2
- AHDC1 | c.2944G>A p.A982T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs752525457, COSV55937883; called by muse, mutect2, varscan2
- AHNAK | c.10565C>T p.P3522L | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779201811, COSV57207766; called by muse, mutect2, varscan2
- AKAP6 | c.3424C>T p.R1142* | Nonsense Mutation (SNP) | VAF 124/286 reads (43%) | catalogued as COSV55222637; called by muse, mutect2, varscan2
- AKAP8 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs974441300, COSV99511888; called by muse, mutect2, varscan2
- ALPK3 | c.4234C>T p.R1412* | Nonsense Mutation (SNP) | VAF 122/294 reads (41%) | catalogued as rs1431206462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200965524, COSV58465627; called by muse, mutect2, varscan2
- AMOTL1 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759303351; called by muse, mutect2, varscan2
- ANK1 | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 193/526 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs762078890; called by muse, mutect2, varscan2
- ANK1 | c.1282dup p.A428Gfs*43 | Frame Shift Ins (INS) | VAF 173/499 reads (35%) | catalogued as rs769735016; called by mutect2, pindel, varscan2
- ANKDD1B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1262014940; called by muse, mutect2, varscan2
- ANKLE2 | c.1354-8del | Splice Region (DEL) | VAF 46/140 reads (33%) | catalogued as rs749179890; called by mutect2, varscan2
- ANKRD26 | c.1110dup p.E371Rfs*5 | Frame Shift Ins (INS) | VAF 46/156 reads (29%) | catalogued as rs775948884; called by mutect2, varscan2
- ANKRD36 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs375602029; called by muse, mutect2, varscan2
- ANO7 | c.1247G>A p.R416Q (on ENST00000274979; = p.R362Q on NM_001370694.2) | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.15); catalogued as rs373704127; called by muse, mutect2, varscan2
- AP1M1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 56/151 reads (37%) | catalogued as rs774557887; called by muse, mutect2, varscan2
- APLP1 | c.701G>C p.G234A | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.188); catalogued as COSV55702494; called by muse, mutect2, varscan2
- APOBEC3H | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs997573747; called by muse, mutect2, varscan2
- ARAP1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs1441837998; called by muse, varscan2
- ARAP2 | c.4502C>T p.P1501L | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58283840; called by muse, mutect2, varscan2
- ARHGAP22 | c.989-5G>A | Splice Region (SNP) | VAF 177/486 reads (36%) | catalogued as rs1245708787; called by muse, mutect2, varscan2
- ARHGEF10 | c.3646G>A p.V1216I (on ENST00000398564; = p.V1191I on NM_014629.4) | Missense Mutation (SNP) | VAF 124/306 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.317); catalogued as rs577376669, COSV50644719; called by muse, varscan2
- ARHGEF12 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34726241; called by muse, mutect2, varscan2
- ARHGEF28 | c.3526C>T p.R1176C | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756948344, COSV55250155; called by muse, mutect2, varscan2
- ARHGEF33 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1323857602; called by muse, varscan2
- ARHGEF5 | c.4243C>T p.R1415C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1198010687; called by mutect2, varscan2
- ARHGEF9 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs781858542, COSV53634623; called by muse, mutect2, varscan2
- ARMC1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs781374786; called by muse, mutect2, varscan2
- ARMC4 | c.2980G>A p.A994T | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs369022423, COSV100537518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ART5 | c.679del p.H227Mfs*18 | Frame Shift Del (DEL) | VAF 115/343 reads (34%) | catalogued as rs748137393; called by mutect2, pindel, varscan2
- ASF1B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs1451875604; called by muse, mutect2, varscan2
- ASH1L | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 98/464 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs374072309; called by muse, mutect2, varscan2
- ASL | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 226/542 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs372774556, CD910616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN1 | c.3482A>G p.Y1161C | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62492752; called by muse, mutect2, varscan2
- ATF6B | c.1992del p.S665Rfs*46 | Frame Shift Del (DEL) | VAF 62/254 reads (24%) | catalogued as rs1562900790; called by mutect2, pindel, varscan2
- ATG4B | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 107/306 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238724360, COSV60350833; called by muse, mutect2, varscan2
- ATMIN | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs772805437, COSV55146067; called by muse, mutect2, varscan2
- ATOH1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1026411537; called by muse, mutect2, varscan2
- ATP13A1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as rs765900327; called by muse, mutect2, varscan2
- ATP13A2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 210/504 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1443334892, COSV58701485; called by muse, mutect2, varscan2
- ATXN2L | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1233456996; called by muse, mutect2, varscan2
- AVL9 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs748745500, COSV59465498; called by muse, mutect2, varscan2
- BANF1 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 23/690 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV56463973; called by muse, mutect2
- BCAS3 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 70/169 reads (41%) | catalogued as rs746825060, COSV101174998; called by muse, mutect2, varscan2
- BCL3 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as rs1385163490, COSV99378304; called by muse, mutect2, varscan2
- BCL6B | c.1323C>T p.H441= | Splice Region (SNP) | VAF 82/190 reads (43%) | catalogued as rs769111877, COSV53428502; called by muse, mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs756382429; called by mutect2, pindel
- BCORL1 | c.4408G>A p.D1470N | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs200861335; called by muse, mutect2, varscan2
- BEND3 | c.1648G>A p.G550S | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.028); catalogued as rs782397162, COSV100944529; called by muse, mutect2, varscan2
- BEST3 | c.1154A>G p.H385R | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs375857714; called by muse, mutect2, varscan2
- BHLHE22 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs767517575; called by muse, mutect2, varscan2
- BICRAL | c.2227A>G p.M743V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs373666939; called by muse, mutect2, varscan2
- BPGM | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.924); catalogued as rs772421290; called by muse, mutect2, varscan2
- BRCA2 | c.7985C>T p.T2662M | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs431825362, COSV99061603; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- BRD3 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs200316883; called by muse, mutect2, varscan2
- BTBD7 | c.3003dup p.Q1002Tfs*5 | Frame Shift Ins (INS) | VAF 161/475 reads (34%) | catalogued as rs762347380; called by mutect2, pindel, varscan2
- C14orf39 | c.1762del p.*588Efs*16 | Frame Shift Del (DEL) | VAF 50/110 reads (45%) | catalogued as rs780875081; called by mutect2, varscan2
- C1D | c.359dup p.N120Kfs*17 | Frame Shift Ins (INS) | VAF 53/219 reads (24%) | catalogued as rs776000138; called by mutect2, pindel, varscan2
- C1S | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs782484390, COSV61070311; called by muse, mutect2, varscan2
- C20orf85 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148848088; called by muse, mutect2, varscan2
- C5AR1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.794); catalogued as COSV61892771; called by muse, mutect2, varscan2
- CACNA1A | c.3995C>T p.A1332V | Missense Mutation (SNP) | VAF 129/375 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs751518122; called by muse, mutect2, varscan2
- CACNA1C | c.3079C>T p.R1027W | Missense Mutation (SNP) | VAF 177/434 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779062610, COSV59694720; called by muse, mutect2, varscan2
- CACNA1D | c.3556C>T p.R1186W (on ENST00000350061 / NM_001128840.3; = p.R1206W on NM_000720.4) | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV55451901; called by muse, mutect2, varscan2
- CACNA2D3 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 142/364 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs775275975, COSV55510818; called by muse, varscan2
- CALR3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 220/556 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs756445681, COSV54171853; called by muse, mutect2, varscan2
- CAMSAP1 | c.3089C>T p.T1030I | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1446884265; called by muse, mutect2, varscan2
- CASKIN1 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1006428427; called by muse, mutect2, varscan2
- CATSPERD | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 125/341 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs762200295; called by muse, mutect2, varscan2
- CAVIN1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63812380; called by muse, mutect2, varscan2
- CBARP | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99289989; called by muse, mutect2, varscan2
- CBFA2T3 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 130/326 reads (40%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs746178109; called by muse, mutect2, varscan2
- CCDC157 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs376667398; called by muse, mutect2, varscan2
- CCDC168 | c.30del p.V12* | Frame Shift Del (DEL) | VAF 45/117 reads (38%) | catalogued as COSV59505832; called by mutect2, pindel, varscan2
- CCN6 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 145/352 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs782703789, COSV100037059; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCNT1 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV56064925; called by muse, mutect2, varscan2
- CD37 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs780075647; called by muse, mutect2, varscan2
- CD93 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1489790839, COSV55663553; called by muse, mutect2, varscan2
- CDHR1 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as rs1330494642; called by muse, mutect2
- CDK13 | c.4094G>A p.R1365Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1257385562, COSV51699186; called by muse, mutect2, varscan2
- CEBPZ | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs527616050, COSV50018906; called by muse, varscan2
- CELSR1 | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 110/291 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53089785; called by muse, mutect2, varscan2
- CEMIP | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 273/682 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99586713; called by muse, mutect2, varscan2
- CENPT | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs745568473; called by muse, mutect2, varscan2
- CEP57 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 161/409 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as rs753867312; called by muse, mutect2, varscan2
- CERS2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs140031607; called by muse, mutect2, varscan2
- CES4A | c.536+6G>A | Splice Region (SNP) | VAF 20/289 reads (7%) | catalogued as rs544371690; called by muse, mutect2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 66/152 reads (43%) | catalogued as rs751492244; called by mutect2, varscan2
- CFHR1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 173/482 reads (36%) | catalogued as rs771183075, COSV57629309; called by muse, mutect2, varscan2
- CHD3 | c.5833G>A p.A1945T (on ENST00000330494 / NM_001005273.3; = p.A1911T on NM_005852.4) | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs138945661; called by muse, mutect2, varscan2
- CHD8 | c.5273G>A p.R1758H (on ENST00000646647 / NM_001170629.2; = p.R1479H on NM_020920.4) | Missense Mutation (SNP) | VAF 145/360 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755975357, COSV63037488; called by muse, mutect2, varscan2
- CHD9 | c.7022G>A p.R2341Q | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs1356995081; called by muse, mutect2, varscan2
- CHERP | c.2411C>T p.S804L | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV52225964; called by muse, mutect2, varscan2
- CHRDL2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144018357; called by muse, mutect2, varscan2
- CHST6 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 152/571 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as CM032872, COSV60002198; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 46/90 reads (51%) | catalogued as rs752250702; called by mutect2, varscan2
- CKMT2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780793438; called by muse, mutect2, varscan2
- CLCN7 | c.981+1G>A p.X327_splice | Splice Site (SNP) | VAF 194/489 reads (40%) | catalogued as rs111940275; called by muse, mutect2, varscan2
- CLIC6 | c.1504G>A p.V502I (on ENST00000360731 / NM_001317009.2; = p.V484I on NM_053277.3) | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142788359; called by muse, mutect2, varscan2
- CNKSR1 | c.1535dup p.P513Tfs*9 (on ENST00000374253 / NM_001297647.2; = p.P506Tfs*9 on NM_006314.3) | Frame Shift Ins (INS) | VAF 138/602 reads (23%) | catalogued as rs753922055; called by mutect2, varscan2
- CNTN5 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs368554933; called by muse, varscan2
- COA7 | c.502A>G p.M168V | Missense Mutation (SNP) | VAF 163/401 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764076308; called by muse, mutect2, varscan2
- COL15A1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 119/324 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187697004, CM142349; called by muse, mutect2, varscan2
- COL17A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 230/551 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs568269377, COSV62226880; called by muse, mutect2, varscan2
- COL18A1 | c.2020C>T p.R674W (on ENST00000359759 / NM_130444.3; = p.R439W on NM_030582.4) | Missense Mutation (SNP) | VAF 123/335 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs376722572, COSV100700883; called by muse, mutect2, varscan2
- COL21A1 | c.758del p.K253Rfs*2 | Frame Shift Del (DEL) | VAF 35/79 reads (44%) | catalogued as rs773380190; called by mutect2, varscan2
- COL9A2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs930549037; called by muse, mutect2, varscan2
- CPEB2 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 144/369 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.741); catalogued as rs759238935, COSV52592629; called by muse, mutect2, varscan2
- CPNE2 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 155/406 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99321130; called by muse, mutect2, varscan2
- CPSF1 | c.3826C>A p.R1276S | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV58235532; called by muse, mutect2, varscan2
- CSPG4 | c.3518G>A p.R1173H | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs138695207; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 80/209 reads (38%) | catalogued as rs767756120; called by mutect2, varscan2
- CTAGE6 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs770780800, COSV69918576; called by muse, mutect2, varscan2
- CTDP1 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 275/667 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs147722483; called by muse, mutect2, varscan2
- CTNNBL1 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs760964033, COSV63743596; called by muse, mutect2, varscan2
- CTXN2 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 160/442 reads (36%) | catalogued as rs756847045; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 66/220 reads (30%) | catalogued as rs751187768; called by mutect2, varscan2
- DBH | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 126/503 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs779175184; called by muse, mutect2, varscan2
- DCAF12L1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV64421788; called by muse, mutect2
- DCBLD1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); catalogued as rs192563915; called by muse, mutect2, varscan2
- DCHS1 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as rs146159630; called by muse, mutect2, varscan2
- DDX21 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 193/466 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs758474376, COSV62556858; called by muse, mutect2, varscan2
- DDX49 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763850904, COSV55355227; called by muse, mutect2, varscan2
- DENND1C | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs1161544479; called by muse, mutect2, varscan2
- DGAT1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 28/546 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV60047266; called by muse, mutect2
- DGKQ | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.073); catalogued as rs1354009552, COSV56616668; called by muse, mutect2, varscan2
- DHRS4 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.747); catalogued as rs375092227; called by muse, mutect2, varscan2
- DHX36 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57676836; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs771360300; called by mutect2, varscan2
- DIP2A | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 91/200 reads (46%) | catalogued as COSV100594935; called by muse, mutect2, varscan2
- DIPK2A | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 129/305 reads (42%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.984); catalogued as rs201605316, COSV59857819; called by muse, mutect2, varscan2
- DISP3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV53827540; called by muse, mutect2, varscan2
- DMRTA1 | c.504dup p.G169Rfs*51 | Frame Shift Ins (INS) | VAF 62/200 reads (31%) | catalogued as rs746316567; called by mutect2, pindel, varscan2
- DMWD | c.1366del p.L456Wfs*203 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs746317972; called by mutect2, varscan2
- DMXL1 | c.7525G>A p.A2509T | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1336830751, COSV60716775; called by muse, mutect2, varscan2
- DNAH2 | c.9565G>A p.V3189I | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs375285205; called by muse, mutect2, varscan2
- DND1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 104/251 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV56905358; called by muse, mutect2, varscan2
- DNHD1 | c.6031C>T p.R2011W | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1390219751; called by muse, mutect2, varscan2
- DOCK10 | c.6418G>A p.E2140K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as rs200577403; called by muse, mutect2, varscan2
- DOCK5 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs372729869; called by muse, mutect2, varscan2
- DPYSL4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1378531905, COSV58307562; called by muse, mutect2, varscan2
- DRD5 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs557030473; called by muse, mutect2, varscan2
- DSCAM | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV68026236; called by muse, mutect2
- DST | c.9244C>T p.R3082W | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs372197874; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 56/175 reads (32%) | catalogued as COSV56128968; called by muse, mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- EARS2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770477636, COSV101492165; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs776999101; called by muse, mutect2, varscan2
- EFCAB5 | c.450dup p.L151Tfs*3 | Frame Shift Ins (INS) | VAF 40/134 reads (30%) | catalogued as rs760813779; called by mutect2, varscan2
- EFNB3 | c.13del p.H5Ifs*54 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | catalogued as rs745309220; called by mutect2, pindel, varscan2
- EGFR | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 208/534 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV51777649; called by muse, mutect2, varscan2
- ELF4 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs371747723; called by muse, mutect2, varscan2
- ELFN2 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.09); catalogued as rs369045365; called by muse, mutect2, varscan2
- EPHA10 | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1418851758; called by muse, mutect2
- EPHA3 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60716544; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1213661579; called by muse, mutect2, varscan2
- EPPK1 | c.6002C>T p.A2001V | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs367640831; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 72/428 reads (17%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERN2 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 27/541 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1392960972, COSV56837724; called by muse, mutect2
- ESPL1 | c.5093G>A p.R1698H | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs931976880, COSV57758555; called by muse, mutect2, varscan2
- ESPNL | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs966722090; called by muse, mutect2, varscan2
- ETNK1 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1407639254; called by muse, mutect2, varscan2
- ETV4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs746305316; called by muse, mutect2, varscan2
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | catalogued as rs760182064; called by mutect2, varscan2
- EXTL3 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 278/690 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217786288, COSV99594041; called by muse, mutect2, varscan2
- F13B | c.1054A>G p.K352E | Missense Mutation (SNP) | VAF 173/451 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs1435619176; called by muse, mutect2, varscan2
- FAH | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 184/465 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143243347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM184B | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs376901720; called by muse, mutect2, varscan2
- FAM241B | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 211/547 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762044523, COSV100958424, COSV64768184; called by muse, mutect2, varscan2
- FAM83H | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 191/479 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs565353939, COSV62028831; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 58/168 reads (35%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs746983128; called by mutect2, varscan2
- FASN | c.6766G>A p.V2256M | Missense Mutation (SNP) | VAF 255/664 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.896); catalogued as rs17848949; called by muse, mutect2, varscan2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs1566257864; called by mutect2, varscan2
- FBXL6 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.078); catalogued as rs782379592; called by muse, mutect2
- FBXO34 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 148/424 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs375077319; called by muse, mutect2, varscan2
- FERD3L | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs768552326, COSV99285195; called by muse, mutect2, varscan2
- FERMT3 | c.1495G>A p.E499K (on ENST00000279227 / NM_178443.3; = p.E495K on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/336 reads (40%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.577); catalogued as rs199681648, COSV54178172; called by muse, mutect2, varscan2
- FGD1 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 268/679 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1421947550, COSV100911074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD6 | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1398241928; called by muse, mutect2, varscan2
- FGF1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 131/343 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.404); catalogued as rs145843967; called by muse, varscan2
- FGFR1OP2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 63/171 reads (37%) | catalogued as rs1406442660, COSV99987087; called by muse, mutect2, varscan2
- FHAD1 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs764165573; called by muse, mutect2, varscan2
- FLG | c.11870A>G p.H3957R | Missense Mutation (SNP) | VAF 322/899 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100912342; called by muse, mutect2, varscan2
- FLOT2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 110/269 reads (41%) | catalogued as rs1468983072; called by muse, mutect2, varscan2
- FLT4 | c.2443A>G p.I815V | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs781112074; called by muse, mutect2, varscan2
- FOCAD | c.2170A>G p.I724V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs758552009; called by muse, mutect2, varscan2
- FOXD1 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 123/301 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.24); catalogued as rs1454007948, COSV100197620; called by muse, mutect2
- FPR2 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749741937, COSV100389176; called by muse, mutect2, varscan2
- FREM3 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1467496408; called by muse, mutect2, varscan2
- FRMD6 | c.965G>A p.R322H (on ENST00000344768 / NM_001267046.2; = p.R314H on NM_152330.4) | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1381185536, COSV61088038; called by muse, mutect2, varscan2
- FRMPD1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746113446, COSV66700067; called by muse, mutect2, varscan2
- FZD7 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376228466; called by muse, mutect2, varscan2
- FZR1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58052144; called by muse, mutect2, varscan2
- GABBR2 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 262/639 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV52296198; called by mutect2, varscan2
- GAP43 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.197); catalogued as COSV59349004; called by muse, mutect2, varscan2
- GARNL3 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 124/328 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as rs769788720; called by muse, mutect2, varscan2
- GARRE1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.991); catalogued as rs976224078; called by muse, mutect2, varscan2
- GATAD2B | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 188/552 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1347107092, COSV64083348; called by muse, mutect2, varscan2
- GBP2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs369681409; called by muse, mutect2, varscan2
- GBP6 | c.1760del p.N587Mfs*18 | Frame Shift Del (DEL) | VAF 118/311 reads (38%) | catalogued as rs1557544730; called by mutect2, pindel, varscan2
- GDF2 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs556004917; ClinVar: uncertain significance; called by muse, mutect2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 24/93 reads (26%) | catalogued as rs761897305; called by mutect2, varscan2
- GGT2 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1316847610; called by mutect2, varscan2
- GJB3 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as CM051931; called by muse, mutect2, varscan2
- GLT1D1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs760181717, COSV55890033; called by muse, mutect2, varscan2
- GMPS | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745389093, COSV55807998; called by muse, mutect2, varscan2
- GNAZ | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1432707029; called by muse, mutect2, varscan2
- GNGT2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 114/311 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1172469007, COSV55929816; called by muse, mutect2, varscan2
- GOLGA3 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.312); catalogued as rs866008346, COSV52642796, COSV52644949; called by muse, mutect2, varscan2
- GPATCH2L | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 86/206 reads (42%) | catalogued as COSV55047758; called by muse, mutect2, varscan2
- GPATCH8 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 171/441 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.978); catalogued as rs1194385217; called by muse, mutect2, varscan2
- GPC1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as rs780671031; called by muse, mutect2, varscan2
- GPD2 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 117/310 reads (38%) | catalogued as rs1010988379; called by muse, varscan2
- GPER1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs926969843, COSV52468741; called by muse, mutect2, varscan2
- GPR35 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs775602865, COSV60576857; called by muse, mutect2, varscan2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 112/280 reads (40%) | catalogued as rs770829884; called by mutect2, varscan2
- GPR68 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs1278730454; called by muse, mutect2, varscan2
- GPRC5D | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 143/322 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs751439160, COSV99964241; called by muse, mutect2, varscan2
- GRIK5 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs938007633, COSV53475633; called by muse, mutect2, varscan2
- GRIN2B | c.1934G>A p.S645N | Missense Mutation (SNP) | VAF 17/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205918; called by muse, mutect2
- GRIN3A | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62451393; called by muse, mutect2, varscan2
- GRM1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 190/481 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs553512718, COSV51109088; called by muse, mutect2, varscan2
- GRPEL1 | c.499G>T p.G167* | Nonsense Mutation (SNP) | VAF 169/385 reads (44%) | catalogued as COSV53826623; called by muse, mutect2, varscan2
- GRWD1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754046830; called by muse, mutect2, varscan2
- GUCA1A | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs926923152; called by muse, mutect2, varscan2
- HAPLN4 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 148/371 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as COSV52271362; called by muse, mutect2, varscan2
- HAS3 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 118/520 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs930891636, COSV99544900; called by muse, mutect2, varscan2
- HCFC2 | c.2002A>G p.S668G | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1308037218; called by muse, mutect2, varscan2
- HCRTR2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 263/655 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.288); catalogued as COSV63795207; called by muse, mutect2, varscan2
- HDAC4 | c.2399del p.P800Lfs*30 | Frame Shift Del (DEL) | VAF 128/407 reads (31%) | catalogued as rs748900140; called by mutect2, pindel, varscan2
- HEBP2 | c.593del p.N198Mfs*26 | Frame Shift Del (DEL) | VAF 81/239 reads (34%) | catalogued as rs769528102, COSV100874953; called by mutect2, pindel, varscan2
- HHIPL2 | c.1186C>T p.R396* | Nonsense Mutation (SNP) | VAF 101/232 reads (44%) | catalogued as rs779442680; called by muse, mutect2, varscan2
- HIF3A | c.1567C>T p.R523C (on ENST00000377670 / NM_152795.4; = p.R454C on NM_022462.4) | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs955256023, COSV52198975; called by muse, mutect2, varscan2
- HLA-DOB | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 208/561 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs144504518; called by muse, mutect2, varscan2
- HNF1A | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 229/610 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs768602671, CX1310935; called by muse, mutect2, varscan2
- HNRNPDL | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs768442894; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs752165954; called by muse, mutect2, varscan2
- HS6ST1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); catalogued as rs550230520; called by muse, mutect2, varscan2
- HSD17B10 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 308/804 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as CM1411978; called by muse, varscan2
- IGSF9B | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs756885918; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV100147047, COSV100148571, COSV56290459; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- IPP | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 107/297 reads (36%) | catalogued as rs757516477, COSV63432781; called by muse, mutect2, varscan2
- IQGAP3 | c.4379A>G p.Q1460R | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs745334511; called by muse, mutect2, varscan2
- IRF3 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs369466676; called by muse, mutect2, varscan2
- IRX4 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV51473923; called by muse, varscan2
- ITGAV | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as rs199804238; called by muse, varscan2
- IWS1 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); catalogued as rs1178033610; called by muse, varscan2
- JAKMIP1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV51523049; called by muse, mutect2, varscan2
- JPH3 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.707); catalogued as rs566027477; called by muse, mutect2, varscan2
- JPH4 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100689429; called by muse, mutect2
- JUP | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 233/637 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs782529328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KATNB1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs782226002, COSV65559665; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 132/310 reads (43%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNH5 | c.11dup p.K5Qfs*21 | Frame Shift Ins (INS) | VAF 63/195 reads (32%) | catalogued as rs769410349; called by mutect2, pindel, varscan2
- KCNJ5 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 280/668 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as rs752310426, COSV100610756, COSV57969048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK2 | c.865G>A p.V289M (on ENST00000444842 / NM_001017425.3; = p.V274M on NM_014217.4) | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67208015; called by muse, mutect2, varscan2
- KCP | c.1001G>A p.R334H (on ENST00000620378; = p.R391H on NM_001366122.1) | Missense Mutation (SNP) | VAF 142/328 reads (43%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.868); catalogued as rs764780035, COSV52820387; called by muse, mutect2, varscan2
- KDM3B | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 96/256 reads (38%) | catalogued as COSV100070378; called by muse, mutect2, varscan2
- KDM5B | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1282352157, COSV52507353; called by muse, mutect2, varscan2
- KIAA0100 | c.151dup p.W51Lfs*8 | Frame Shift Ins (INS) | VAF 78/210 reads (37%) | catalogued as rs1339576763; called by mutect2, varscan2
- KIAA1614 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775217655, COSV62552685; called by muse, mutect2
- KIDINS220 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs970613821, COSV56750940; called by muse, mutect2, varscan2
- KIDINS220 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 74/210 reads (35%) | catalogued as rs200360669, COSV56756012, COSV99874990; called by muse, mutect2, varscan2
- KIF17 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 169/418 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.257); catalogued as COSV56117154; called by muse, mutect2, varscan2
- KIF26B | c.4637G>A p.R1546Q | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs546761347; called by muse, mutect2, varscan2
- KLHL13 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 169/424 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs927520673, COSV53254145; called by muse, mutect2, varscan2
- KLHL23 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752643631; called by muse, mutect2, varscan2
- KMT5A | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs186822980; called by muse, varscan2
- KPNB1 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 157/444 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393584201, COSV51596909; called by muse, mutect2, varscan2
- KRR1 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs114719907; called by muse, varscan2
- KRT38 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 172/457 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs748640709, COSV55845954, COSV55846677; called by muse, mutect2, varscan2
- KRT84 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1283454012, COSV57771418; called by muse, mutect2, varscan2
- KSR1 | c.872del p.P291Hfs*36 (on ENST00000644974 / NM_001367810.1; = p.P154Hfs*36 on NM_014238.2) | Frame Shift Del (DEL) | VAF 72/166 reads (43%) | catalogued as rs750491454; called by mutect2, varscan2
- LAMA5 | c.11026G>A p.A3676T | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs376263803; called by muse, mutect2, varscan2
- LAMB2 | c.4882dup p.A1628Gfs*4 | Frame Shift Ins (INS) | VAF 293/831 reads (35%) | catalogued as rs747602505; called by mutect2, pindel, varscan2
- LAMC3 | c.4051C>T p.R1351W | Missense Mutation (SNP) | VAF 182/485 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as rs749904181, COSV100735973; called by muse, mutect2, varscan2
- LAMTOR4 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 180/469 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1344849728, COSV57585104; called by muse, mutect2, varscan2
- LBR | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 233/542 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs761503513, COSV55292069; called by muse, mutect2, varscan2
- LCMT2 | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.877); catalogued as rs1238873745, COSV59790664; called by muse, mutect2, varscan2
- LDLRAD2 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs765147969, COSV100760776; called by muse, mutect2, varscan2
- LDLRAD4 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 113/342 reads (33%) | catalogued as rs770553486, COSV63334286; called by muse, mutect2, varscan2
- LIN7B | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 142/371 reads (38%) | catalogued as COSV99674464; called by muse, mutect2, varscan2
- LINGO2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV58063236; called by muse, mutect2, varscan2
- LINGO4 | c.1671G>A p.W557* | Nonsense Mutation (SNP) | VAF 112/267 reads (42%) | catalogued as COSV64313756; called by muse, mutect2, varscan2
- LMNA | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 141/387 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.427); catalogued as rs1212920276, CM1510386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LONP1 | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 137/307 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs141916070; called by muse, varscan2
- LONP1 | c.2476A>G p.M826V | Missense Mutation (SNP) | VAF 144/368 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs1345467036; called by muse, varscan2
- LRATD1 | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs867444164, COSV54472344; called by muse, mutect2, varscan2
- LRP1 | c.7867C>T p.R2623C | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs868577215; called by muse, mutect2
- LRRC59 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1411219306; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624del p.I1542Ffs*17 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | catalogued as rs745692987; called by mutect2, varscan2
- LRRN3 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 86/231 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1301367470; called by muse, mutect2, varscan2
- LSR | c.1269dup p.S424Qfs*10 (on ENST00000361790; = p.S405Qfs*10 on NM_015925.6) | Frame Shift Ins (INS) | VAF 42/123 reads (34%) | catalogued as rs771235856; called by mutect2, varscan2
- MAGI1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs764775560; called by muse, mutect2
- MAN2A2 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 122/326 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs199840427, COSV64638103; called by muse, mutect2, varscan2
- MAN2B1 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 187/528 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs762841449; called by muse, mutect2, varscan2
- MAP1A | c.5246G>A p.S1749N | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100289236; called by muse, mutect2, varscan2
- MAP1A | c.7862G>A p.R2621H | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs375219661; called by muse, mutect2, varscan2
- MAP2K3 | c.124dup p.R42Pfs*17 (on ENST00000342679 / NM_145109.3; = p.R13Pfs*17 on NM_002756.4) | Frame Shift Ins (INS) | VAF 68/322 reads (21%) | catalogued as COSV100384541; called by mutect2, varscan2
- MAP3K12 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs754240127, COSV57231852; called by muse, mutect2, varscan2
- MAP3K15 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV58827547; called by muse, varscan2
- MAP3K2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61296331; called by muse, mutect2
- MAPK13 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 82/221 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs149860912; called by muse, mutect2, varscan2
- MAPK4 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 183/437 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs754028426, COSV68543069; called by muse, mutect2, varscan2
- MAPKAPK3 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63598523; called by muse, mutect2, varscan2
- MARK1 | c.2205del p.E736Rfs*54 | Frame Shift Del (DEL) | VAF 114/313 reads (36%) | catalogued as rs1558333111; called by mutect2, pindel, varscan2
- MBD3 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 158/366 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1056083253, COSV99336832; called by muse, varscan2
- MBD3L2B | c.363del p.T122Rfs*49 | Frame Shift Del (DEL) | VAF 47/425 reads (11%) | catalogued as rs1224277525; called by mutect2, pindel, varscan2
- MED12L | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 115/218 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56395222; called by muse, mutect2, varscan2
- MED13L | c.3100G>A p.G1034R | Missense Mutation (SNP) | VAF 129/307 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1565997652; called by muse, mutect2, varscan2
- MED25 | c.1087G>A p.G363R | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.303); catalogued as rs145507089; called by muse, mutect2, varscan2
- MED25 | c.2213T>C p.M738T | Missense Mutation (SNP) | VAF 166/430 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.396); catalogued as rs1333507247; called by muse, mutect2, varscan2
- MED27 | c.871G>A p.G291S | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.442); catalogued as rs774276967; called by muse, mutect2, varscan2
- METTL17 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1273908233; called by muse, mutect2, varscan2
- MGAT4C | c.1174dup p.I392Nfs*2 | Frame Shift Ins (INS) | VAF 69/216 reads (32%) | catalogued as rs746398787; called by mutect2, varscan2
- MIA2 | c.1089dup p.D364Rfs*5 | Frame Shift Ins (INS) | VAF 43/108 reads (40%) | catalogued as rs538500709; called by mutect2, varscan2
- MKNK2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs145739021; called by muse, mutect2, varscan2
- MLC1 | c.135del p.C46Afs*12 | Frame Shift Del (DEL) | VAF 228/631 reads (36%) | catalogued as CD151534; called by mutect2, pindel, varscan2
- MLXIPL | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs1274074665, COSV57668261; called by muse, mutect2, varscan2
- MMD2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.395); catalogued as rs778116678, COSV68661062; called by muse, mutect2, varscan2
- MMP19 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747927965, COSV59452807; called by muse, mutect2, varscan2
- MMP3 | c.190dup p.I64Nfs*33 | Frame Shift Ins (INS) | VAF 89/244 reads (36%) | catalogued as rs782038929; called by mutect2, varscan2
- MOBP | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 197/491 reads (40%) | PolyPhen possibly damaging (0.731); catalogued as rs1351982984, COSV100215420, COSV60655376; called by muse, mutect2, varscan2
- MRPL1 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 104/263 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs147627539; called by muse, mutect2, varscan2
- MRPL22 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs546990845; called by muse, mutect2, varscan2
- MTHFD1L | c.1331T>C p.L444P | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63365211; called by muse, mutect2, varscan2
- MTNR1B | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 194/433 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369557205; called by muse, mutect2, varscan2
- MTOR | c.6325C>T p.R2109* | Nonsense Mutation (SNP) | VAF 41/181 reads (23%) | catalogued as rs1386760919, COSV63869894; called by muse, mutect2, varscan2
- MTPAP | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 184/472 reads (39%) | catalogued as rs773094167, COSV53934807; called by muse, mutect2, varscan2
- MUC17 | c.5281G>A p.V1761I | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs781393368, COSV60282413; called by muse, mutect2, varscan2
- MYH7B | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377713561; called by muse, mutect2, varscan2
- MYO1F | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 169/503 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754452234, COSV57791886; called by muse, mutect2, varscan2
- MYOC | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 147/582 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs771122834, CM981351, COSV50677446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYPN | c.2986C>T p.R996* | Nonsense Mutation (SNP) | VAF 185/518 reads (36%) | catalogued as rs753094063; called by muse, mutect2, varscan2
- NAA15 | c.2269A>G p.R757G | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1242438557, COSV99649949; called by muse, mutect2, varscan2
- NAA50 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as rs374332039; called by muse, mutect2
- NASP | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63113518; called by muse, mutect2, varscan2
- NBPF10 | c.10756A>C p.S3586R | Missense Mutation (SNP) | VAF 178/922 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1553779395; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NDN | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.486); catalogued as COSV59359546; called by muse, mutect2, varscan2
- NDST4 | c.1813dup p.T605Nfs*22 | Frame Shift Ins (INS) | VAF 46/138 reads (33%) | catalogued as rs1215333204; called by mutect2, pindel, varscan2
- NEB | c.7864G>A p.V2622M | Missense Mutation (SNP) | VAF 156/378 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs905660353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN2 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1199121316; called by muse, mutect2, varscan2
- NIPBL | c.7044del p.K2348Nfs*8 | Frame Shift Del (DEL) | VAF 53/275 reads (19%) | catalogued as COSV99242703; called by mutect2, pindel, varscan2
- NKG7 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389909; called by muse, mutect2, varscan2
- NKPD1 | c.1683G>A p.W561* | Nonsense Mutation (SNP) | VAF 46/116 reads (40%) | catalogued as COSV100521574; called by muse, mutect2, varscan2
- NLGN1 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs965800500; called by muse, mutect2, varscan2
- NLRP6 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1490499073, COSV56458499, COSV56462673; called by muse, mutect2, varscan2
- NOBOX | c.1345C>T p.R449* | Nonsense Mutation (SNP) | VAF 34/79 reads (43%) | catalogued as rs760393493, COSV99779822; called by muse, mutect2, varscan2
- NPHS1 | c.2028del p.E677Rfs*33 | Frame Shift Del (DEL) | VAF 50/226 reads (22%) | catalogued as rs751927994; called by mutect2, pindel, varscan2
- NPR1 | c.1818dup p.N607Qfs*21 | Frame Shift Ins (INS) | VAF 54/143 reads (38%) | catalogued as rs772189906; called by mutect2, varscan2
- NR1H2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs772224466, COSV53800029; called by muse, mutect2, varscan2
- NR1H2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs777958888; called by muse, mutect2, varscan2
- NR2F6 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs569917645, COSV52243130; called by muse, mutect2, varscan2
- NRBP2 | c.448T>C p.W150R | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1166673439; called by muse, mutect2, varscan2
- NRXN3 | c.809C>T p.T270M (on ENST00000557594 / NM_001272020.2; = p.T902M on NM_004796.6) | Missense Mutation (SNP) | VAF 128/317 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs746669604, COSV55322053; called by muse, mutect2, varscan2
- NSD1 | c.7721C>T p.P2574L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs150977055, COSV100728850; called by muse, mutect2, varscan2
- NUDT7 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 138/359 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as rs541244539, COSV99216088; called by muse, mutect2, varscan2
- NYAP1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1313203126; called by muse, mutect2, varscan2
- OPN4 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs762507074, COSV54115394; called by muse, mutect2, varscan2
- OR2A5 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 167/400 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs1016779536; called by muse, mutect2, varscan2
- OR2F2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs375593151; called by muse, mutect2, varscan2
- OR4D5 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs762546954, COSV58309529; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 168/402 reads (42%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52B4 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.663); catalogued as rs767367023, COSV68769096; called by mutect2, varscan2
- OR5R1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs760788614; called by muse, mutect2, varscan2
- OR5R1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 126/379 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs759298137; called by muse, mutect2, varscan2
- OR6C65 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as COSV101110196; called by muse, mutect2, varscan2
- OR8B3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs755136502; called by mutect2, pindel
- P2RY8 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1265740684; called by muse, mutect2, varscan2
- PABPC1L | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1263635958; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.817G>A p.A273T (on ENST00000259318 / NM_001136562.3; = p.A504T on NM_007203.5) | Missense Mutation (SNP) | VAF 115/309 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.197); catalogued as rs777202417; called by muse, mutect2, varscan2
- PAN3 | c.336del p.K115Rfs*38 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs1566125870; called by mutect2, varscan2
- PARD6A | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304403989, COSV54666807; called by muse, mutect2, varscan2
- PAX8 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 246/576 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs727504066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH7 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV62338034; called by muse, mutect2, varscan2
- PCDHA1 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.367); catalogued as COSV65376996; called by muse, mutect2, varscan2
- PCDHGA1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 219/536 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV65295957; called by muse, mutect2, varscan2
- PCDHGC4 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs763174232; called by muse, varscan2
- PCDHGC4 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 115/307 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as rs1360545946, COSV52759774; called by muse, mutect2, varscan2
- PCSK9 | c.1486C>G p.R496G | Missense Mutation (SNP) | VAF 161/392 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.145); catalogued as CM066163; called by muse, varscan2
- PDE11A | c.2405del p.N802Tfs*10 | Frame Shift Del (DEL) | VAF 84/245 reads (34%) | catalogued as COSV53695154; called by mutect2, pindel, varscan2
- PDE3B | c.2802A>T p.K934N | Missense Mutation (SNP) | VAF 141/369 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99963255; called by muse, mutect2, varscan2
- PDE4DIP | c.4447C>T p.R1483W | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781998818; called by muse, mutect2, varscan2
- PELP1 | c.2392del p.L798Cfs*14 | Frame Shift Del (DEL) | VAF 56/136 reads (41%) | catalogued as rs752653446, COSV99342923; called by mutect2, varscan2
- PEX11B | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs201998667; called by muse, mutect2, varscan2
- PFAS | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780319540, COSV58980825; called by muse, mutect2, varscan2
- PFKFB1 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 58/207 reads (28%) | PolyPhen benign (0.371); catalogued as rs368904040; called by muse, mutect2, varscan2
- PGAP6 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs745477438, COSV51742856; called by muse, mutect2
- PGM5 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 96/264 reads (36%) | catalogued as rs1554675796; called by muse, mutect2, varscan2
- PGM5 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782281328, COSV101123445; called by muse, mutect2, varscan2
- PGPEP1L | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs752090113; called by muse, mutect2, varscan2
- PHB | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 168/462 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs1277922087, COSV100303164; called by muse, mutect2, varscan2
- PHF1 | c.1471del p.H491Tfs*3 (on ENST00000374516 / NM_024165.3; = p.T456Lfs*18 on NM_002636.5) | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | catalogued as COSV53385741; called by mutect2, pindel, varscan2
- PHKA2 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 204/529 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.223); catalogued as COSV66052890; called by muse, mutect2, varscan2
- PI4KA | c.4381G>A p.G1461S | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.015); catalogued as rs565662495; called by muse, mutect2, varscan2
- PIAS3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.961); catalogued as rs781864436; called by muse, mutect2
- PIDD1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 116/232 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs550392917; called by muse, mutect2, varscan2
- PIK3R1 | c.1156C>T p.R386* (on ENST00000521381 / NM_181523.3; = p.R116* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 56/137 reads (41%) | catalogued as COSV57126203, COSV57144628; called by muse, mutect2, varscan2
- PIK3R1 | c.1448C>T p.A483V (on ENST00000521381 / NM_181523.3; = p.A213V on NM_181504.4) | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99141343; called by muse, mutect2, varscan2
- PKD1 | c.10760C>T p.A3587V (on ENST00000262304 / NM_001009944.3; = p.A3586V on NM_000296.4) | Missense Mutation (SNP) | VAF 209/506 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs753473169; called by muse, mutect2, varscan2
- PKD1 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); catalogued as rs752035888, COSV99239371; called by muse, mutect2, varscan2
- PKN3 | c.1392dup p.C465Lfs*11 | Frame Shift Ins (INS) | VAF 108/280 reads (39%) | catalogued as rs1216019307; called by mutect2, pindel, varscan2
- PKP2 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 218/534 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as CM119564, COSV50754683; called by muse, mutect2, varscan2
- PLA2R1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 119/288 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs201969665; called by muse, mutect2, varscan2
- PLCH2 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs755583411; called by muse, mutect2, varscan2
- PLD4 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as rs776057514; called by muse, mutect2, varscan2
- PLEKHG4 | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 172/428 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs752381179, COSV58574446; called by muse, mutect2, varscan2
- PLEKHH3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1438119357; called by muse, mutect2, varscan2
- PLEKHM1 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs780046946, COSV69598913, COSV69599204; called by muse, mutect2
- PLXNA1 | c.4883G>A p.R1628H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1265186462, COSV52526680; called by muse, mutect2
- PLXNA4 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 231/598 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218616402, COSV58117646; called by muse, mutect2, varscan2
- PNMA8B | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 142/327 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs1166689466, COSV66537462; called by muse, mutect2, varscan2
- PNPLA3 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 227/539 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372035117; called by muse, mutect2, varscan2
- POLD1 | c.342del p.P116Hfs*53 | Frame Shift Del (DEL) | VAF 98/285 reads (34%) | catalogued as COSV101486889; called by mutect2, pindel, varscan2
- POLDIP3 | c.909T>G p.C303W | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459745170, COSV52808624; called by muse, mutect2, varscan2
- POLE2 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.217); catalogued as rs773282710; called by muse, mutect2, varscan2
- POLM | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 144/321 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs775660212; called by muse, mutect2, varscan2
- POU4F2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs990275856, COSV55583596; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.272); catalogued as rs1462233665; called by muse, mutect2, varscan2
- PPARD | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1453840099, COSV61099453; called by muse, varscan2
- PPP1R12A | c.3047A>G p.D1016G | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV54111346; called by muse, mutect2, varscan2
- PPP1R16A | c.1333del p.H445Tfs*15 | Frame Shift Del (DEL) | VAF 88/251 reads (35%) | catalogued as rs777096925; called by mutect2, varscan2
- PPP1R35 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1210520040; called by muse, mutect2, varscan2
- PPP1R3A | c.2060del p.G687Efs*9 | Frame Shift Del (DEL) | VAF 191/572 reads (33%) | catalogued as COSV52877132; called by mutect2, pindel, varscan2
- PRDM15 | c.647del p.P216Rfs*22 | Frame Shift Del (DEL) | VAF 108/282 reads (38%) | catalogued as COSV54156899; called by mutect2, varscan2
- PRF1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs747380397, CM021668, COSV100942619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1019925698, COSV58059933; called by muse, mutect2, varscan2
- PRPF6 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 205/517 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV53878495; called by muse, mutect2, varscan2
- PRR22 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs759133214; called by muse, mutect2
- PRRC2B | c.1955del p.P652Rfs*24 | Frame Shift Del (DEL) | VAF 69/267 reads (26%) | catalogued as rs1452197257, COSV61934348; called by pindel, varscan2
- PSD3 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs189891634, COSV58965108; called by muse, mutect2, varscan2
- PSMA8 | c.150del p.K50Nfs*12 | Frame Shift Del (DEL) | VAF 76/202 reads (38%) | catalogued as rs749240094; called by mutect2, varscan2
- PTCH1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 92/239 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs767601899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGES2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 106/223 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1040048423; called by muse, mutect2, varscan2
- PTGFRN | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.365); catalogued as rs150849305; called by muse, mutect2, varscan2
- PTPRN | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV55347016; called by muse, mutect2, varscan2
- PTPRQ | c.5836G>A p.V1946I (on ENST00000616559; = p.V1904I on NM_001145026.2) | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.341); catalogued as rs575071305, COSV57056778; called by muse, mutect2, varscan2
- PTPRS | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.909); catalogued as rs150939732; called by muse, varscan2
- PTPRT | c.2443C>T p.R815C | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.39); catalogued as rs773152433, COSV61959419, COSV61981777; called by muse, mutect2, varscan2
- PTX4 | c.1191dup p.G398Rfs*? (on ENST00000447419 / NM_001328608.2; = p.G393Rfs*? on NM_001013658.1) | Frame Shift Ins (INS) | VAF 66/194 reads (34%) | catalogued as rs772722517; called by mutect2, varscan2
- PUM2 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as rs760721555; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 101/338 reads (30%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- PXMP2 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs984884395; called by muse, mutect2, varscan2
- PYCR1 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs1279036604; called by muse, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as rs755727862; called by mutect2, varscan2
- R3HDM4 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs375768350, COSV64293452; called by muse, mutect2, varscan2
- RAD54B | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs189646756, COSV52594675; called by muse, varscan2
- RADX | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs755480947, COSV65317669; called by muse, mutect2, varscan2
- RAPGEF4 | c.1227+9_1227+10dup p.X409_splice | Splice Site (INS) | VAF 34/110 reads (31%) | catalogued as rs1360657390; called by mutect2, varscan2
- RASA1 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM083065; called by muse, mutect2, varscan2
- RB1 | c.219_220dup p.A74Efs*4 | Frame Shift Ins (INS) | VAF 93/272 reads (34%) | catalogued as COSV57297594; called by mutect2, varscan2
- RBM33 | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as rs756039779; called by muse, mutect2, varscan2
- RERE | c.1828G>A p.G610S | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs781019481; called by muse, mutect2, varscan2
- RFC4 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.675); catalogued as rs370796190; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNF14 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61662171; called by muse, mutect2, varscan2
- RNF213 | c.5483G>A p.G1828D | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100299354; called by muse, mutect2, varscan2
- RNF213 | c.11926C>T p.R3976C | Missense Mutation (SNP) | VAF 205/510 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs780312086, COSV60401908; called by muse, mutect2, varscan2
- RNF213 | c.12305G>A p.R4102H | Missense Mutation (SNP) | VAF 268/665 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs776689503, COSV60394687, COSV60399450; called by muse, mutect2, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 53/143 reads (37%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- RNF225 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs1182055453; called by muse, mutect2
- RNF25 | c.749dup p.I251Nfs*3 | Frame Shift Ins (INS) | VAF 126/350 reads (36%) | catalogued as rs746813141; called by mutect2, varscan2
- RNF43 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68459927; called by muse, mutect2
- RPAP1 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs144404285; called by muse, mutect2, varscan2
- RPGRIP1L | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 141/368 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs560144848, COSV50918125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL14 | c.41A>G p.Y14C | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs757289887; called by muse, mutect2, varscan2
- RPL26L1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 55/254 reads (22%) | catalogued as rs769115115, COSV99442528; called by muse, mutect2, varscan2
- RPL3L | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as rs1445638539; called by muse, mutect2, varscan2
- RRP9 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs760648950, COSV51754379; called by muse, mutect2, varscan2
- RYBP | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as COSV72180279; called by muse, mutect2, varscan2
- RYR1 | c.5098G>A p.A1700T | Missense Mutation (SNP) | VAF 113/338 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs751849934, COSV100615713; called by muse, mutect2, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 70/146 reads (48%) | catalogued as rs757259031; called by mutect2, varscan2
- SCML4 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as rs775916413, COSV64636645; called by muse, mutect2, varscan2
- SCN10A | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs148046286; called by muse, mutect2, varscan2
- SCN5A | c.5524A>G p.M1842V (on ENST00000333535 / NM_198056.3; = p.M1841V on NM_000335.5) | Missense Mutation (SNP) | VAF 252/675 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs368967393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCRIB | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs781791746; called by muse, mutect2, varscan2
- SDHA | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 162/417 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.057); catalogued as rs375576259; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SDK2 | c.4072C>T p.R1358W | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745336235, COSV101169159; called by muse, mutect2, varscan2
- SELL | c.314G>A p.R105Q (on ENST00000650983; = p.R92Q on NM_000655.5) | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1253642034; called by muse, mutect2, varscan2
- SEMA3A | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs768038554, COSV54890028; called by muse, mutect2, varscan2
- SEMA4B | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762088970, COSV100203184; called by muse, mutect2, varscan2
- SEMA6B | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs186951396; called by muse, mutect2, varscan2
- SENP6 | c.1024_1026del p.N342del | In Frame Del (DEL) | VAF 65/164 reads (40%) | catalogued as rs1351545932; called by mutect2, pindel, varscan2
- SERINC1 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 79/236 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs968662900, COSV100305152; called by muse, mutect2, varscan2
- SERINC4 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs778250947, COSV51048574; called by muse, mutect2, varscan2
- SERPINI1 | c.482-2A>G p.X161_splice | Splice Site (SNP) | VAF 68/194 reads (35%) | catalogued as COSV55515421; called by muse, varscan2
- SFI1 | c.2725G>A p.A909T (on ENST00000400288 / NM_001007467.3; = p.A878T on NM_014775.4) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1241660028; called by muse, mutect2, varscan2
- SFSWAP | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 73/183 reads (40%) | catalogued as rs1221194404, COSV99906281; called by muse, mutect2, varscan2
- SGCB | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs550062936; called by muse, mutect2
- SGO1 | c.955del p.T319Lfs*34 | Frame Shift Del (DEL) | VAF 48/127 reads (38%) | catalogued as rs748571368; called by mutect2, pindel, varscan2
- SH2B1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs558967163, COSV59461868; called by muse, mutect2, varscan2
- SH3BP2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 143/378 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as rs1177351370; called by muse, mutect2, varscan2
- SH3PXD2A | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1009820415; called by muse, mutect2, varscan2
- SHANK3 | c.2773G>A p.A925T | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1360881506; called by muse, mutect2, varscan2
- SIGLEC11 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.544); catalogued as COSV70222086; called by muse, mutect2, varscan2
- SIN3A | c.367-2A>G p.X123_splice | Splice Site (SNP) | VAF 34/74 reads (46%) | catalogued as COSV64583476; called by muse, varscan2
- SIN3B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 158/409 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs1172751156, COSV56130873; called by muse, mutect2, varscan2
- SKI | c.1928A>G p.Q643R | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1288017380, COSV66014708; called by muse, mutect2, varscan2
- SLC15A1 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV64732681, COSV64733385; called by muse, mutect2, varscan2
- SLC16A11 | c.827del p.G276Dfs*43 (on ENST00000308009; = p.G252Dfs*43 on NM_153357.3) | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | catalogued as COSV99080391; called by mutect2, pindel, varscan2
- SLC38A10 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55843272; called by muse, mutect2, varscan2
- SLC39A1 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57844908; called by muse, mutect2
- SLC44A2 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 44/121 reads (36%) | catalogued as rs777757978; called by muse, mutect2, varscan2
- SLC4A3 | c.2652dup p.S885Qfs*83 | Frame Shift Ins (INS) | VAF 94/260 reads (36%) | catalogued as rs760972612; called by mutect2, varscan2
- SLC4A4 | c.2842C>T p.R948C (on ENST00000264485 / NM_001098484.3; = p.R904C on NM_003759.4) | Missense Mutation (SNP) | VAF 201/446 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772578212, COSV52623444; called by muse, mutect2, varscan2
- SLC5A2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 170/479 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs760532652, COSV57894019; called by muse, mutect2, varscan2
- SLC9A8 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 156/416 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs112865334; called by muse, mutect2, varscan2
- SLCO1A2 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368672331; called by muse, mutect2, varscan2
- SLFN13 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs146777094; called by muse, mutect2, varscan2
- SLITRK3 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53846993; called by muse, mutect2, varscan2
- SLITRK5 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 169/404 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs376984309, COSV100281244; called by muse, mutect2, varscan2
- SMAD3 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 170/406 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM145135, COSV100529417, COSV59280325, COSV59283909; called by muse, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 86/269 reads (32%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SMARCA2 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 224/496 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1563724432; called by muse, varscan2
- SMARCA2 | c.3962C>T p.T1321M | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61810960; called by muse, mutect2, varscan2
- SMARCA4 | c.3104T>C p.L1035P | Missense Mutation (SNP) | VAF 125/587 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60805428; called by muse, mutect2, varscan2
- SMARCC1 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs1162318390, COSV54381884; called by muse, mutect2, varscan2
- SMC1A | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 176/511 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100447612, COSV59129650; called by muse, mutect2, varscan2
- SNX20 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs562563894, COSV56057635; called by muse, mutect2, varscan2
- SNX29 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 254/675 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164978597; called by muse, mutect2, varscan2
- SOGA1 | c.3989C>T p.A1330V | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs774887637; called by muse, mutect2, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 140/420 reads (33%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SORBS3 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 105/300 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs143257462; called by muse, mutect2, varscan2
- SORBS3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1297856428; called by muse, mutect2, varscan2
- SPATA2 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs143193219; called by muse, mutect2, varscan2
- SPEM2 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs752912269, COSV60367595; called by muse, mutect2, varscan2
- SPTBN2 | c.5906T>C p.M1969T | Missense Mutation (SNP) | VAF 203/538 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV59453428; called by muse, mutect2, varscan2
- SREBF2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 235/578 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs777697017; called by muse, mutect2, varscan2
- SS18L1 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); catalogued as rs1180386184; called by muse, mutect2, varscan2
- STAB1 | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 108/265 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV58732640; called by muse, mutect2, varscan2
- STON2 | c.2710G>A p.V904M (on ENST00000649389 / NM_001366849.2; = p.V847M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/371 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1162905535, COSV50842691, COSV50847584; called by muse, mutect2, varscan2
- STRC | c.3166C>T p.H1056Y | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.523); catalogued as rs1275974309; called by muse, mutect2, varscan2
- STX16 | c.487G>A p.A163T (on ENST00000371141 / NM_001001433.3; = p.A142T on NM_003763.6) | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.142); catalogued as rs1431618445, COSV56608033; called by muse, mutect2, varscan2
- STXBP5L | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs747217368, COSV56501092; called by muse, mutect2, varscan2
- SUDS3 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs1471032611, COSV100820007; called by muse, varscan2
- SULT1C3 | c.41del p.K14Sfs*10 | Frame Shift Del (DEL) | VAF 35/92 reads (38%) | catalogued as rs770034585; called by mutect2, pindel, varscan2
- SV2A | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 187/429 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782791082; called by muse, mutect2, varscan2
- SYNE1 | c.4943C>T p.T1648M (on ENST00000367255 / NM_182961.4; = p.T1655M on NM_033071.3) | Missense Mutation (SNP) | VAF 132/339 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs199797561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT11 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 95/230 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.053); catalogued as rs201050124, COSV64175646, COSV64175996; called by muse, mutect2, varscan2
- TAF15 | c.1300G>A p.G434S (on ENST00000605844 / NM_139215.3; = p.G431S on NM_003487.4) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs766057799; called by muse, mutect2, varscan2
- TAF5 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs931530179; called by muse, mutect2, varscan2
- TARBP1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1281537198; called by muse, mutect2, varscan2
- TARBP2 | c.839G>A p.R280H (on ENST00000266987 / NM_134323.2; = p.R259H on NM_004178.4) | Missense Mutation (SNP) | VAF 147/339 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs753986429; called by muse, mutect2, varscan2
- TBKBP1 | c.727dup p.A243Gfs*48 | Frame Shift Ins (INS) | VAF 17/48 reads (35%) | catalogued as rs756336411; called by mutect2, pindel, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 121/355 reads (34%) | catalogued as rs748952707, COSV56876494; called by mutect2, pindel, varscan2
- TBX3 | c.2026G>A p.A676T (on ENST00000257566 / NM_016569.4; = p.A656T on NM_005996.4) | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1013102657, COSV57472702, COSV57473679; called by muse, mutect2, varscan2
- TBX3 | c.1550C>T p.P517L (on ENST00000257566 / NM_016569.4; = p.P497L on NM_005996.4) | Missense Mutation (SNP) | VAF 128/315 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1450269147; called by muse, mutect2, varscan2
- TBXAS1 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 192/523 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773129737; called by muse, mutect2, varscan2
- TCEA3 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs777318907, COSV71532059; called by muse, mutect2, varscan2
- TCERG1 | c.1881dup p.R628Tfs*6 | Frame Shift Ins (INS) | VAF 44/110 reads (40%) | catalogued as rs751330927; called by mutect2, varscan2
- TDRD9 | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59154546; called by muse, mutect2, varscan2
- TECRL | c.832G>T p.G278* | Nonsense Mutation (SNP) | VAF 47/133 reads (35%) | catalogued as COSV67086670, COSV67090989; called by muse, mutect2, varscan2
- TECTA | c.5635G>A p.A1879T | Missense Mutation (SNP) | VAF 221/533 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as rs766297094, COSV50696560; called by muse, mutect2, varscan2
- TEDC1 | c.1088G>A p.R363Q (on ENST00000392523 / NM_001367178.1; = p.R294Q on NM_001134875.1) | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs782038842, COSV58155828; called by muse, mutect2, varscan2
- TEP1 | c.5400del p.K1801Sfs*3 | Frame Shift Del (DEL) | VAF 92/297 reads (31%) | catalogued as COSV52994591; called by mutect2, pindel, varscan2
- TEPSIN | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139708500; called by muse, mutect2, varscan2
- TEX11 | c.1390G>A p.A464T (on ENST00000344304; = p.A449T on NM_031276.3) | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV100721935; called by muse, mutect2, varscan2
- TEX13C | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100809329; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | catalogued as rs753315680; called by mutect2, pindel, varscan2
- TEX2 | c.2332G>A p.V778M (on ENST00000583097 / NM_001288733.2; = p.V785M on NM_018469.5) | Missense Mutation (SNP) | VAF 140/387 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs527473632, COSV51978302; called by muse, mutect2, varscan2
- TFCP2L1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as rs766924189, COSV55293575; called by muse, mutect2, varscan2
- TGM1 | c.1570G>A p.G524S | Missense Mutation (SNP) | VAF 206/532 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765914927, CM129548, COSV52862796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THAP1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs767519301, CM101447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THBS4 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760925141, COSV63469239; called by muse, mutect2, varscan2
- THEG | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770542115, COSV61074403; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 65/166 reads (39%) | catalogued as rs746975641; called by mutect2, varscan2
- THOC5 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 118/221 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as rs769986095; called by muse, mutect2, varscan2
- TIE1 | c.743del p.P248Lfs*117 | Frame Shift Del (DEL) | VAF 108/395 reads (27%) | catalogued as rs1417872933, COSV100992023; called by mutect2, pindel, varscan2
- TIMELESS | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.332); catalogued as rs758113731; called by muse, mutect2, varscan2
- TINF2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs200025766; called by muse, mutect2, varscan2
- TLE1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs558704626; called by muse, mutect2, varscan2
- TMCC1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs771506179, COSV67872896; called by muse, mutect2
- TMEM104 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs149214532; called by muse, mutect2, varscan2
- TMEM145 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 140/324 reads (43%) | catalogued as rs755937975, COSV56627601; called by muse, mutect2, varscan2
- TMEM259 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs903539756, COSV52258929; called by muse, mutect2, varscan2
- TMEM51 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as rs779269565, COSV101051562; called by muse, mutect2, varscan2
- TMEM63A | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753018849; called by muse, mutect2, varscan2
- TMEM86B | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 196/513 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372172769; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 97/258 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs750403186; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs771999459, COSV64423313; called by muse, mutect2, varscan2
- TNFRSF11A | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs1435790714; called by muse, mutect2, varscan2
- TNFRSF25 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1185142187, COSV61067502; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3121G>A p.G1041R | Missense Mutation (SNP) | VAF 148/331 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs757701921; called by muse, mutect2, varscan2
- TNRC18 | c.4457G>A p.R1486Q | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as rs570365021, COSV68166613; called by muse, mutect2, varscan2
- TNXB | c.6929G>A p.R2310H (on ENST00000647633; = p.R2063H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs747409043; called by muse, mutect2, varscan2
- TOGARAM1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 66/201 reads (33%) | catalogued as rs144734587; called by muse, mutect2, varscan2
- TPX2 | c.713T>A p.L238H | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55922652; called by muse, mutect2, varscan2
- TRAV22 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs1373680489; called by muse, mutect2, varscan2
- TRGV1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs752530767; called by muse, mutect2, varscan2
- TRIM43 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 198/587 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs371687609; called by muse, mutect2, varscan2
- TRIM66 | c.3580C>T p.R1194* | Nonsense Mutation (SNP) | VAF 86/202 reads (43%) | catalogued as rs1256801890, COSV55124791; called by muse, mutect2, varscan2
- TRIO | c.3951G>A p.T1317= | Splice Region (SNP) | VAF 65/169 reads (38%) | catalogued as rs752164149, COSV60088648; called by muse, mutect2, varscan2
- TRMT2A | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 101/350 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs752575735, COSV52813413; called by muse, mutect2, varscan2
- TRPM3 | c.714G>T p.K238N (on ENST00000357533 / NM_001366142.2; = p.K83N on NM_020952.6) | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs746747793; called by muse, mutect2, varscan2
- TSC22D4 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 135/293 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs868585166, COSV55723553; called by muse, mutect2, varscan2
- TSPAN10 | c.456del p.L154Cfs*19 (on ENST00000574882 / NM_001290212.1; = p.L116Cfs*19 on NM_031945.4) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs771262491, COSV100148738, COSV60773593; called by mutect2, pindel, varscan2
- TSPYL5 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs768336569, COSV100438992; called by muse, mutect2, varscan2
- TSSK2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.427); catalogued as rs140549220; called by muse, mutect2, varscan2
- TTN | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 134/356 reads (38%) | PolyPhen benign (0.005); catalogued as rs34337578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTPAL | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764981264, COSV52828227; called by muse, mutect2, varscan2
- TUBB4A | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 175/416 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs587777429, CM146108, COSV51155246; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 51/144 reads (35%) | catalogued as rs760251146; called by mutect2, varscan2
- TYK2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.715); catalogued as rs561118378; called by muse, mutect2, varscan2
- UCK2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.932); catalogued as COSV100903053; called by muse, mutect2, varscan2
- UNC13B | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 83/398 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs368769067; called by muse, mutect2, varscan2
- UNC13C | c.4386G>C p.Q1462H | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.135); catalogued as COSV52898959; called by muse, mutect2, varscan2
- UNC5B | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 166/429 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747312686, COSV58977174; called by muse, mutect2, varscan2
- UNC5B | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 115/292 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as rs151335269; called by muse, mutect2, varscan2
- UNC80 | c.7570A>G p.I2524V | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs915501062; called by muse, mutect2, varscan2
- USB1 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 192/422 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531886363, COSV54624141; called by muse, mutect2, varscan2
- USP32 | c.2719A>G p.N907D | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV56279338; called by muse, mutect2, varscan2
- USP9X | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 53/239 reads (22%) | catalogued as COSV61075087; called by muse, mutect2, varscan2
- VAV1 | c.2334G>A p.V778= | Splice Region (SNP) | VAF 58/131 reads (44%) | catalogued as rs1183815100, COSV58379171; called by muse, mutect2, varscan2
- VCL | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 320/766 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs199751261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VCPIP1 | c.105dup p.L36Afs*51 | Frame Shift Ins (INS) | VAF 48/134 reads (36%) | catalogued as rs755078234; called by mutect2, varscan2
- VEGFB | c.386del p.K129Rfs*5 | Frame Shift Del (DEL) | VAF 56/123 reads (46%) | catalogued as rs747177567, COSV100374813; called by mutect2, varscan2
- VENTX | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs776964051, COSV58084164; called by muse, mutect2, varscan2
- VEZT | c.220del p.S74Lfs*38 | Frame Shift Del (DEL) | VAF 56/196 reads (29%) | catalogued as rs748321397; called by mutect2, varscan2
- VIRMA | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1184219938; called by muse, mutect2, varscan2
- VIT | c.2030G>A p.R677Q (on ENST00000389975 / NM_001177969.1; = p.R692Q on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); catalogued as rs747347674, COSV64898125, COSV64898374; called by muse, mutect2, varscan2
- VMO1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs761864481; called by muse, mutect2
- VPS13B | c.10244C>T p.T3415I | Missense Mutation (SNP) | VAF 117/278 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767783667; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.11242G>T p.G3748C | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62138998; called by muse, mutect2, varscan2
- VPS13C | c.8878G>A p.E2960K (on ENST00000644861 / NM_020821.3; = p.E2917K on NM_017684.5) | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs767073024; called by muse, varscan2
- VPS28 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 26/634 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52873507; called by muse, mutect2
- VTN | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 146/403 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781794064, COSV56872456, COSV56873809; called by muse, mutect2, varscan2
- VWA3A | c.2715del p.S906Afs*8 | Frame Shift Del (DEL) | VAF 79/230 reads (34%) | catalogued as rs778922532, COSV55391225, COSV55391244; called by mutect2, pindel, varscan2
- WASHC1 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 74/480 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1355052746; called by muse, varscan2
- WDR1 | c.1243G>A p.V415I (on ENST00000382452; = p.V275I on NM_005112.5) | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.083); catalogued as rs180996365; called by muse, mutect2, varscan2
- WDR44 | c.2043dup p.V682Sfs*6 | Frame Shift Ins (INS) | VAF 72/194 reads (37%) | catalogued as rs758728740; called by mutect2, pindel, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 71/242 reads (29%) | catalogued as rs1557951659, COSV63058584; called by pindel, varscan2
- WDR59 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1433583872; called by muse, mutect2, varscan2
- WDR86 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1024353200, COSV57838323; called by muse, mutect2
- WIZ | c.3998G>A p.R1333Q (on ENST00000673675 / NM_001371589.1; = p.R238Q on NM_021241.3) | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.722); catalogued as rs199966379; called by muse, mutect2, varscan2
- WWTR1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs188215356; called by muse, mutect2, varscan2
- XAB2 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as rs368990102; called by muse, mutect2, varscan2
- XIRP1 | c.5098C>T p.Q1700* | Nonsense Mutation (SNP) | VAF 153/346 reads (44%) | catalogued as rs749925223; called by muse, mutect2, varscan2
- XKR8 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1174269407; called by muse, mutect2, varscan2
- ZAN | c.7423C>T p.R2475C | Missense Mutation (SNP) | VAF 106/281 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs750922272, COSV61811211; called by muse, mutect2, varscan2
- ZBTB4 | c.2453C>T p.A818V | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as rs1370421713, COSV60140015, COSV60142272; called by muse, mutect2, varscan2
- ZBTB7C | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as rs774550186, COSV59688255; called by muse, mutect2, varscan2
- ZDHHC16 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as rs577013737; called by muse, mutect2, varscan2
- ZFAND3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54724487; called by muse, mutect2, varscan2
- ZFHX3 | c.2287dup p.E763Gfs*26 | Frame Shift Ins (INS) | VAF 124/334 reads (37%) | catalogued as rs760959844; called by mutect2, varscan2
- ZFP36L1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1312701866; called by muse, mutect2, varscan2
- ZFYVE26 | c.4019G>A p.R1340H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs144416809; called by muse, mutect2, varscan2
- ZHX2 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 130/318 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.965); catalogued as rs1429585551, COSV58711267; called by muse, mutect2, varscan2
- ZIK1 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56738796; called by muse, mutect2, varscan2
- ZNF287 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754238613; called by muse, mutect2
- ZNF34 | c.664dup p.T222Nfs*6 | Frame Shift Ins (INS) | VAF 34/176 reads (19%) | catalogued as rs751927309; called by mutect2, varscan2
- ZNF429 | c.1504del p.I502Ffs*182 | Frame Shift Del (DEL) | VAF 105/299 reads (35%) | catalogued as rs1422865370; called by mutect2, pindel, varscan2
- ZNF521 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 155/411 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV64122832; called by muse, mutect2, varscan2
- ZNF548 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs376205703; called by muse, mutect2, varscan2
- ZNF780B | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55464837; called by muse, mutect2, varscan2
- ZNF789 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 95/332 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs779145089; called by muse, mutect2, varscan2
- ZNF831 | c.3313del p.E1105Sfs*73 | Frame Shift Del (DEL) | VAF 55/170 reads (32%) | catalogued as COSV64043003; called by mutect2, pindel, varscan2
- ZNF835 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs776888606, COSV73379670; called by muse, mutect2, varscan2
- ZNF860 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.368); catalogued as rs772716297, COSV100824368; called by muse, varscan2
- ZNFX1 | c.5314C>T p.R1772C | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs369660830; called by muse, mutect2, varscan2
- ZP3 | c.1061-1G>A p.X354_splice (on ENST00000394857 / NM_001110354.2; = p.X303_splice on NM_007155.6) | Splice Site (SNP) | VAF 163/441 reads (37%) | catalogued as COSV60635682; called by muse, mutect2, varscan2
- ZSCAN2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs149816515; called by muse, mutect2, varscan2
- ZSWIM4 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 182/408 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1449347120; called by muse, mutect2, varscan2
- ZZZ3 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs776531392; called by muse, mutect2, varscan2
- ABCB11 | c.416T>A p.I139N | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ABCC1 | c.3204del p.S1069Vfs*5 | Frame Shift Del (DEL) | VAF 88/285 reads (31%) | called by mutect2, pindel, varscan2
- ABCC2 | c.3719T>C p.F1240S | Missense Mutation (SNP) | VAF 40/746 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ABHD17A | c.400C>A p.L134M (on ENST00000292577 / NM_001130111.2; = p.L185M on NM_031213.4) | Missense Mutation (SNP) | VAF 163/445 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ABTB2 | c.2672G>A p.S891N | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- ACADVL | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 173/403 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAM20 | c.1052A>G p.Q351R | Missense Mutation (SNP) | VAF 118/289 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS7 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ADAMTS9 | c.2366A>G p.E789G | Missense Mutation (SNP) | VAF 132/359 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2387dup p.L796Ffs*6 | Frame Shift Ins (INS) | VAF 82/235 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.1783dup p.Y595Lfs*13 | Frame Shift Ins (INS) | VAF 139/440 reads (32%) | called by mutect2, pindel, varscan2
- ADCY2 | c.1770del p.E591Sfs*14 | Frame Shift Del (DEL) | VAF 65/177 reads (37%) | called by mutect2, pindel, varscan2
- ADCY5 | c.2846T>C p.V949A | Missense Mutation (SNP) | VAF 134/341 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ADNP | c.64dup p.I22Nfs*3 | Frame Shift Ins (INS) | VAF 86/224 reads (38%) | called by mutect2, varscan2
- ADRA2A | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.12319G>A p.G4107S | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAP12 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 137/409 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AKNA | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AL121758.1 | c.247del p.H83Ifs*60 | Frame Shift Del (DEL) | VAF 65/337 reads (19%) | called by mutect2, pindel, varscan2
- ALB | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 276/620 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.399); called by mutect2, varscan2
- ALDH16A1 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 10/185 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- ALDH1A3 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 119/335 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ALOX12 | c.1505T>A p.I502N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANK2 | c.5190del p.G1731Vfs*7 | Frame Shift Del (DEL) | VAF 82/263 reads (31%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.4139T>A p.L1380* (on ENST00000611781; = p.L1324* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- ANKRD6 | c.838_839dup p.L281Gfs*125 | Frame Shift Ins (INS) | VAF 95/297 reads (32%) | called by mutect2, varscan2
- ANKS3 | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANXA1 | c.164T>C p.I55T | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ARAP3 | c.3832G>C p.V1278L | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ARHGAP44 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ARHGEF10 | c.2276A>G p.D759G (on ENST00000398564; = p.D734G on NM_014629.4) | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 101/353 reads (29%) | called by mutect2, pindel, varscan2
- ARID3B | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 127/362 reads (35%) | called by mutect2, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 74/191 reads (39%) | called by mutect2, varscan2
- ARMCX6 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 179/448 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ARRB1 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ARSB | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARSD | c.1555C>A p.L519I | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ASAP1 | c.320dup p.L107Ffs*61 | Frame Shift Ins (INS) | VAF 44/128 reads (34%) | called by mutect2, pindel, varscan2
- ASPN | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 131/384 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, varscan2
- ATG12 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 108/225 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, varscan2
- ATM | c.2045T>A p.V682D | Missense Mutation (SNP) | VAF 115/311 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ATP10B | c.807dup p.L270Sfs*23 | Frame Shift Ins (INS) | VAF 111/354 reads (31%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.3574C>T p.Q1192* | Nonsense Mutation (SNP) | VAF 121/273 reads (44%) | called by muse, mutect2, varscan2
1,177 further variants in this file (511 protein-altering or splice-affecting, 380 silent, 286 other) are not listed here.
